Gene-level copy-number profile of tumor specimen TCGA-FG-A87Q-01A from TCGA case TCGA-FG-A87Q, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 61.8 years (22,565 days).
Specimen TCGA-FG-A87Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.7540b5fb-951a-4e95-8175-ce4284456a67.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FG-A87Q-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1d5f8621-2c05-4ee2-a106-ea5b00439901

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 74; copy number 1: 6,075; copy number 2: 48,161; copy number 3: 4,870; copy number 4: 418; copy number 5: 45; copy number 7: 120; copy number 36: 8; copy number 39: 44.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FG-A87Q-01A-11D-A36N-01): tumor purity 0.54, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 74 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:50,780,340–50,974,634, 3 genes: PHBP12, MRPS6P2, CDKN2C.
- chr9:19,789,179–22,455,740, 71 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 217 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:9,553,614–11,823,906, 45 genes, copy number 5 (within-gene range 3–5): AC097493.1, MIR548I2, RPS3AP19, AC105916.1, SNRPCP13, ENPP7P11, FAM86MP, ALG1L3P, Metazoa_SRP, AC098976.1, OR7E35P, SLC2A9, DRD5, RNA5SP154, AC108199.1, SLC2A9-AS1, AC005674.1, WDR1, MIR3138, RNA5SP155, AC093664.1, AC006499.6, AC006499.1, AC006499.8, RAF1P1, AC006499.4, AC006499.2, AC006499.3, AC006499.5, AC006499.7, AC110768.2, ZNF518B, AC005599.1, AC110768.1, CLNK, AC084048.1, LINC02498, MIR572, RNPS1P1, HS3ST1, RNA5SP156, AC006230.1, AC025539.1, AC005699.1, LINC02360.
- chr4:51,843,000–57,478,341, 120 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr7:44,958,999–47,079,128, 44 genes, copy number 39: AC004847.1, MYO1G, SNHG15, SNORA9, CCM2, NACAD, TBRG4, SNORA5A, SNORA5C, SNORA5B, RAMP3, AC073968.2, AC073968.1, ELK1P1, AC073325.1, AC073325.2, ADCY1, SEPTIN7P2, GTF2IP13, RNU6-241P, CICP20, AC096582.1, AC096582.2, RNU6-326P, CCDC201, IGFBP1, IGFBP3, AC073115.2, AC073115.1, FTLP15, TTC4P1, ZNF619P1, AC023669.1, AC023669.2, AC004869.2, AC004869.1, HMGN1P19, AC011294.1, EPS15P1, AC004870.4, AC004870.2, AC004870.3, MRPL42P4, AC004870.1.
- chr7:54,752,250–55,260,256, 8 genes, copy number 36: SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.

Autosomal genes at a single copy (total copy number 1): 6,075. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
